Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A69I, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A69I-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

ICD-O-3

Case Number :

Diagnosis:

A: Gallbladder, cholecystectomy
- Cholelithiasis

B: Lymph nodes, portal, regional resection
- Two lymph nodes with lipid lymphadenopathy, negative for malignancy (0/2)

C: Liver, Segment 4-8, partial hepatectomy

Number of tumors: 1

Tumor #1:

Tumor size: 7.0 cm

Tumor location: Segment 4-8

Histologic tumor type/subtype: hepatocellular carcinoma

Histologic grade: Well differentiated

Tumor necrosis/treatment effect: None

Worst tumor differentiation: Well differentiated

Vascular invasion: None

Perineural invasion: Absent

Capsular invasion: Absent

Margins: negative; 0.5 cm to the black inked parenchymal margin, negative en face left portal vein margin (stitches)

Lymph nodes (including lymph nodes from specimen B): two lymph nodes, negative for malignancy (0/2)

Satellite lesions: No

Background liver: steatohepatitis, grade 2, stage 1-2 (Brunt classification)

Carcinoma, hepatocellular^{NOS}
8/70/13
Site Liver C22.0
Ja 6/3/13

[page 2 of 3]
Other extrahepatic spread: No

Additional findings:

- Biopsy site changes

AJCC Pathologic TNM stage: pT1 pN0

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

D: Soft tissue, omental deposit, excision

- Fibroadipose tissue with fibrosis, dystrophic calcifications, and granulation tissue
- No malignancy identified

Comment:

A reticulin stain confirms the presence of hepatocellular carcinoma.

Background liver shows macrovesicular steatosis involving approximately 30-40% of the hepatic parenchyma. Ballooned hepatocytes containing Mallory's hyaline are readily identified, and moderate numbers of inflammatory cells, mainly neutrophils, are clustered around and within lobular hepatocytes. A trichrome stain shows patchy pericellular and periportal fibrosis. The findings are consistent with steatohepatitis. The presence of Mallory's hyaline and neutrophil-predominant lobular inflammation raises suspicion for alcoholic steatohepatitis. Clinical correlation is recommended.

Clinical History:

year-old male with biopsy proven HCC.

"Please also comment on the health of normal liver away from the tumor, ?cirrhosis."

Gross Description:

Received are four formalin-filled containers.

Container A is additionally labeled "gallbladder." It holds a 6.2 x 3.0 x 1.2 cm gallbladder. The serosal surface is tan/green and smooth. The gallbladder is received disrupted along the neck. There are three black granular stones within the lumen, 1.5 x 0.6 x 0.2 cm in aggregate. The mucosa is green and velvety and the wall is 0.2 cm thick.

[page 3 of 3]
Block summary:

A1 - cystic duct margin and representative sections
Tissue remains in formalin.

Container B is additionally labeled "portal node." It holds a 5.0 x 4.1 x 1.1 cm fragment of yellow fatty tissue. Within the tissue there are multiple lymph nodes palpated, the largest is 1.8 cm.

Block summary:

B1 - one lymph node, bisected
B2-B3 - one lymph node, trisected
B4-B5 - non-palpable lymph node
A small amount of tissue remains in formalin

Container C is additionally labeled "liver, Segments 4-8", requisition states "stitch marks left portal vein." It holds a 350 gram, 15.0 x 11.2 x 5.2 cm partial hepatectomy specimen. The specimen is received with two stitches embedded within the surgical margin, roughly 2 cm from each other, and marking the left portal vein per the requisition. The tissue surrounding the stitches are inked red and the remainder of the surgical margin is inked black. The capsular surface is notable for an area of bulging that is 7.5 x 4.5 cm. Beneath this area within the parenchyma there is a green nodular, well circumscribed firm mass roughly 7.0 x 5.5 x 5.3 cm. There are multiple areas of hemorrhage within the mass. The mass comes to within 0.5 cm of the black inked surgical margin. No additional abnormalities are noted. The remainder of the capsule is dark red to brown, smooth and the parenchyma is tan/brown, firm, and unremarkable.

Block summary:

C1 - tissue beneath stitches, en face
C2 - mass and adjacent ductal structures
C3-C4 - mass and surgical margin, closest approach, perpendicular
C5 - additional section of mass with capsule and adjacent normal liver parenchyma
C6 - liver parenchyma away from mass
A portion of tumor and normal is submitted to Tissue Procurement. Tissue remains in formalin.

Container D is additionally labeled "omental deposit." It holds a 5.2 x 5.1 x 1.5 cm fragment of yellow lobulated fat. Within the center there is a 1.0 x 1.0 x 0.8 cm tan firm nodule. The cut surface is tan/orange and firm. The specimen is entirely submitted in blocks D1-D2; fat remains in formalin.

Source: NCI Genomic Data Commons file 0d1edd87-90cf-4481-803b-32f5f7c66ce2 (TCGA-BC-A69I.94F0B317-494A-4467-94A2-5004010E133F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).